Somatic mutation profile of tumor specimen TCGA-A4-7585-01A (aliquot TCGA-A4-7585-01A-11D-2136-08) from TCGA case TCGA-A4-7585, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.8 years (24,778 days).
Specimen TCGA-A4-7585-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 821acaa2-891f-4038-b8cd-53966fd0fee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7585-11A (Solid Tissue Normal), aliquot TCGA-A4-7585-11A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4f3f855-1c0f-4f72-8b8f-9465d410d9e3

The open-access MAF lists 76 somatic variants for this specimen: 62 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Frame Shift Del 8, Nonsense Mutation 6, Splice Site 3, In Frame Del 2, Frame Shift Ins 2, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRC | c.2403+1G>A p.X801_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as rs1553243550, COSV100722275, COSV61421327; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA13 | c.6409G>A p.D2137N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.034); catalogued as COSV70046847; called by muse, mutect2
- ABCA5 | c.493G>C p.A165P | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as COSV67015782, COSV67019367; called by muse, mutect2, varscan2
- ABCG2 | c.587T>G p.I196R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52950005; called by muse, mutect2, varscan2
- ADGRB2 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV57079442; called by muse, mutect2, varscan2
- ADGRL2 | c.4006C>G p.L1336V (on ENST00000370717 / NM_001366005.1; = p.L1280V on NM_012302.4) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.53); catalogued as COSV54691808; called by muse, mutect2, varscan2
- BICRAL | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as COSV58405607, COSV58408759; called by muse, mutect2, varscan2
- BRINP3 | c.2180T>A p.L727* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as COSV66542880; called by muse, mutect2, varscan2
- CAD | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs757926493, COSV53032537; called by muse, mutect2, varscan2
- CAPN7 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV53781071; called by muse, mutect2, varscan2
- CIITA | c.395T>C p.M132T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs781384047, COSV60862677; called by muse, mutect2, varscan2
- CNTN1 | c.895A>C p.N299H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61646315; called by muse, mutect2, varscan2
- COL5A1 | c.5371-1G>C p.X1791_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | catalogued as COSV65675726; called by muse, mutect2, varscan2
- COL6A3 | c.4946A>G p.N1649S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55112837; called by muse, mutect2, varscan2
- CRTC2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV57845960; called by muse, mutect2, varscan2
- DARS1 | c.125-1G>T p.X42_splice | Splice Site (SNP) | VAF 24/118 reads (20%) | catalogued as COSV51542209; called by muse, mutect2, varscan2
- DOCK2 | c.3635A>G p.K1212R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV56991450; called by muse, mutect2, varscan2
- FAM50B | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1484366992, COSV66654735; called by mutect2, varscan2
- GAN | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs368372086; called by muse, mutect2, varscan2
- GCN1 | c.2436G>A p.E812= | Splice Region (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100324819, COSV56115556; called by muse, mutect2
- HAS2 | c.108T>A p.F36L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58262666, COSV58267720; called by muse, mutect2, varscan2
- HTRA1 | c.1411A>T p.I471F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV64565446; called by muse, mutect2, varscan2
- ITSN1 | c.4115C>A p.S1372Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67157703; called by muse, mutect2, varscan2
- KIAA1109 | c.3493G>T p.E1165* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV52695462; called by muse, mutect2, varscan2
- KIF5C | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV68483882; called by muse, mutect2, varscan2
- KRT9 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV55855662, COSV55855843; called by muse, mutect2, varscan2
- MRPL2 | c.620T>G p.I207S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV52439586; called by muse, mutect2, varscan2
- NFKBIA | c.877T>A p.S293T | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV53755113; called by muse, mutect2, varscan2
- PKDREJ | c.5560A>C p.N1854H | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV53546471, COSV53553654; called by muse, mutect2, varscan2
- PPM1D | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 42/136 reads (31%) | catalogued as COSV59958339; called by muse, mutect2, varscan2
- PPP6R2 | c.2333G>T p.S778I (on ENST00000216061 / NM_001365836.1; = p.S751I on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV53299322; called by muse, mutect2, varscan2
- PTPRN | c.2176T>G p.C726G | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV55352675; called by muse, mutect2, varscan2
- PTPRS | c.1934A>T p.E645V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.41); catalogued as COSV53639504; called by muse, mutect2, varscan2
- RELN | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59036629; called by muse, mutect2, varscan2
- SENP6 | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV64190849; called by muse, mutect2, varscan2
- SHPRH | c.4310G>C p.R1437P (on ENST00000275233 / NM_001042683.3; = p.R1441P on NM_173082.3) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51618826; called by muse, mutect2, varscan2
- SLC23A2 | c.929T>A p.L310Q | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57780533; called by muse, mutect2, varscan2
- SLC28A2 | c.1561A>C p.I521L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV61665455; called by muse, mutect2, varscan2
- SLC36A2 | c.1142T>A p.L381Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV58865363; called by muse, mutect2, varscan2
- SPATA9 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV57225187; called by muse, mutect2, varscan2
- STAT6 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55670890, COSV55674546; called by muse, mutect2, varscan2
- TAF1B | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV55160375; called by muse, mutect2, varscan2
- THSD7B | c.2703C>A p.S901R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1180688760, COSV55742871; called by muse, mutect2, varscan2
- TMEM266 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV66381957; called by muse, mutect2, varscan2
- TOE1 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV59157946; called by muse, mutect2, varscan2
- TREX1 | c.706A>T p.T236S (on ENST00000625293 / NM_033629.6; = p.T226S on NM_007248.5) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV56498204, COSV99603915; called by muse, mutect2, varscan2
- TSGA10 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV61825990; called by muse, mutect2, varscan2
- URGCP | c.980T>G p.I327S (on ENST00000453200 / NM_001077663.3; = p.I318S on NM_017920.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV56253344; called by muse, mutect2, varscan2
- VPS8 | c.3487C>T p.H1163Y (on ENST00000625842 / NM_001349294.1; = p.H1161Y on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1367031459, COSV54997712; called by muse, mutect2, varscan2
- ZNF681 | c.1845G>C p.E615D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV68074158, COSV68075915; called by muse, mutect2
- ABCA13 | c.7027dup p.S2343Ffs*12 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- ARAP1 | c.4015del p.I1339Lfs*10 (on ENST00000393609 / NM_001040118.2; = p.I1094Lfs*10 on NM_015242.4) | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- CACNA1G | c.4769_4770del p.C1590* | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- GAA | c.1749_1750del p.H584Qfs*51 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- LCT | c.3423del p.A1142Pfs*27 | Frame Shift Del (DEL) | VAF 19/155 reads (12%) | called by mutect2, pindel, varscan2
- PCDH18 | c.1200del p.H400Qfs*17 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel, varscan2
- POLB | c.383del p.N128Mfs*5 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- PPRC1 | c.410del p.N137Mfs*79 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- PTCHD1 | c.2323_2324insG p.F775Cfs*11 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- SEC24A | c.439_450del p.S147_N150del | In Frame Del (DEL) | VAF 21/112 reads (19%) | called by mutect2, pindel, varscan2
- SMC1A | c.192_194del p.I65del | In Frame Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- TECTA | c.319del p.I107Ffs*16 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- CIART | c.792T>A p.T264= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV51746386; called by muse, mutect2, varscan2
- FASTKD3 | c.576T>C p.P192= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as COSV52947169; called by muse, mutect2, varscan2
- KIAA0895 | c.765C>T p.F255= (on ENST00000297063 / NM_001100425.2; = p.F204= on NM_015314.3) | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV51711805, COSV51714399; called by muse, mutect2, varscan2
- KIAA1549 | c.1737G>A p.P579= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs570277151, COSV54330692; ClinVar: likely benign; called by muse, mutect2
- KRT77 | c.49C>A p.R17= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV59241725; called by muse, mutect2, varscan2
- MTFMT | c.1146T>G p.V382= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV54980132, COSV99584283; called by muse, varscan2
- MYO18B | c.7062C>G p.L2354= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as COSV59142686, COSV59150524; called by muse, mutect2, varscan2
- NSD1 | c.5349C>T p.N1783= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as CD052485, COSV61785884; called by muse, mutect2, varscan2
- SETD5 | c.3124T>C p.L1042= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs780757418, COSV56717888; called by muse, mutect2
- SLC39A9 | c.12C>T p.F4= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV50362689; called by muse, mutect2, varscan2
- SPATA46 | c.510A>G p.L170= | Silent (SNP) | VAF 50/300 reads (17%) | catalogued as COSV62640684; called by muse, mutect2, varscan2
- TRAV39 | c.324C>T p.A108= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs763625243; called by muse, mutect2, varscan2
- PHB2 | c.711+87G>A | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as rs1555151057, COSV99781298; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.805C>A | RNA (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
